Somatic mutation profile of tumor specimen TCGA-AO-A0JD-01A (aliquot TCGA-AO-A0JD-01A-11W-A071-09) from TCGA case TCGA-AO-A0JD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.8 years (21,831 days).
Specimen TCGA-AO-A0JD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b34f6365-a904-497d-98a3-a1676050e0fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JD-10A (Blood Derived Normal), aliquot TCGA-AO-A0JD-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86a31eb5-3c37-415a-9d9f-98c9a74c34ae

The open-access MAF lists 121 somatic variants for this specimen: 92 protein-altering or splice-affecting, 24 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 24, Nonsense Mutation 9, Splice Site 3, Intron 2, Frame Shift Del 1, 3'UTR 1, 5'Flank 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNA1 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28933383, CM076245, CM962692, CM993940, COSV66836391; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 42/81 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AKAP13 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV63454219; called by muse, mutect2, varscan2
- AQP10 | c.448C>A p.P150T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61474436, COSV61474590, COSV61474821; called by muse, mutect2, varscan2
- ARID2 | c.4364G>A p.S1455N | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100536464; called by muse, mutect2
- ARNT2 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100309163; called by muse, mutect2
- ATG13 | c.794C>A p.S265* | Nonsense Mutation (SNP) | VAF 43/122 reads (35%) | catalogued as COSV100365468, COSV100365497, COSV56318903; called by muse, mutect2, varscan2
- ATP1A3 | c.1603G>A p.E535K (on ENST00000545399 / NM_001256214.2; = p.E522K on NM_152296.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as rs782769181, COSV57486880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATRX | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100969550; called by muse, mutect2
- BCL3 | c.463G>T p.V155F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV51234104; called by muse, mutect2, varscan2
- BCOR | c.1071C>A p.F357L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.977); catalogued as COSV60705376; called by muse, mutect2, varscan2
- C14orf39 | c.774T>G p.F258L | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV100407795; called by muse, mutect2
- CHD9 | c.1288C>G p.H430D | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.027); catalogued as COSV68297846; called by muse, mutect2, varscan2
- CHRNA6 | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774973747, COSV52379244, COSV99373436; called by muse, mutect2, varscan2
- CIBAR1 | c.758G>T p.C253F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.169); catalogued as COSV63897149; called by muse, mutect2, varscan2
- CNTNAP5 | c.3368G>T p.S1123I | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV101443750, COSV70514888; called by muse, mutect2
- COLGALT2 | c.410C>A p.P137Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as COSV62728348; called by muse, mutect2, varscan2
- CYP2A13 | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV57836627, COSV57837507; called by muse, mutect2, varscan2
- DCTN4 | c.644A>C p.K215T | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV69782072; called by muse, mutect2, varscan2
- DOCK11 | c.3472-1G>A p.X1158_splice | Splice Site (SNP) | VAF 91/446 reads (20%) | catalogued as COSV52237274; called by muse, mutect2, varscan2
- DSP | c.2756A>T p.D919V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV65792315; called by muse, mutect2, varscan2
- EHBP1 | c.1141C>G p.P381A | Missense Mutation (SNP) | VAF 15/515 reads (3%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as COSV99861241; called by muse, mutect2
- EPHB1 | c.1720G>A p.V574M | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs548362226, COSV67658837; called by muse, mutect2, varscan2
- ESD | c.511G>C p.A171P | Missense Mutation (SNP) | VAF 74/242 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66340005; called by muse, mutect2, varscan2
- FAT3 | c.1858G>T p.E620* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV53085511, COSV53099679; called by muse, mutect2, varscan2
- FBXO27 | c.757T>G p.F253V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99494674; called by muse, mutect2, varscan2
- FERMT1 | c.757T>C p.S253P | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54092380; called by muse, mutect2, varscan2
- FLG | c.8273G>T p.S2758I | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV64240407; called by muse, mutect2, varscan2
- FLG | c.5654A>G p.H1885R | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV64240409; called by muse, mutect2, varscan2
- GRAMD1C | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63982538; called by muse, mutect2, varscan2
- ITGB4 | c.2590C>G p.L864V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV52324657; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1319C>T p.S440F (on ENST00000439118 / NM_001008949.3; = p.S448F on NM_178495.6) | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as rs772622332, COSV63153318; called by muse, mutect2
- JCAD | c.2344A>T p.S782C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as COSV100948449; called by muse, mutect2
- KCNG4 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV57582861, COSV57583429; called by muse, mutect2, varscan2
- KCNK2 | c.307A>G p.I103V (on ENST00000444842 / NM_001017425.3; = p.I88V on NM_014217.4) | Missense Mutation (SNP) | VAF 118/278 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67204972; called by muse, mutect2, varscan2
- KCTD16 | c.1052T>G p.V351G | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV101568832; called by muse, mutect2
- KIAA1614 | c.2426C>A p.T809N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62550740; called by muse, mutect2, varscan2
- KLC4 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs557603845, COSV52435041; called by muse, mutect2, varscan2
- KRTAP1-5 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.178); catalogued as COSV62624181; called by muse, mutect2, varscan2
- KRTAP10-9 | c.368A>C p.Q123P | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.139); catalogued as COSV59958763; called by muse, mutect2, varscan2
- MAGEA10 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV54883631; called by muse, mutect2, varscan2
- MECP2 | c.1327G>C p.A443P | Missense Mutation (SNP) | VAF 33/174 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs193922677, CM1212525, COSV100318369; called by muse, mutect2, varscan2
- MERTK | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV54927668; called by muse, mutect2, varscan2
- MLC1 | c.386T>C p.F129S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61116824; called by muse, mutect2, varscan2
- MPP4 | c.1694A>T p.D565V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV53804498; called by muse, mutect2, varscan2
- MYBPC1 | c.3355T>A p.C1119S (on ENST00000550270 / NM_206820.2; = p.C1126S on NM_002465.4) | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100638125; called by muse, mutect2
- MYDGF | c.218C>A p.T73N | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53560572; called by muse, mutect2
- NDOR1 | c.764C>T p.S255L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.019); catalogued as rs200133206, COSV61286435; called by muse, mutect2, varscan2
- NOL11 | c.1524C>G p.F508L | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV53523032; called by muse, mutect2, varscan2
- OBI1 | c.600A>C p.L200F | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.523); catalogued as COSV56145296; called by muse, mutect2, varscan2
- OR14A16 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.486); catalogued as COSV62926498; called by muse, mutect2, varscan2
- OR2L2 | c.427A>G p.M143V | Missense Mutation (SNP) | VAF 359/812 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV63551785; called by muse, mutect2, varscan2
- OR2L2 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 135/552 reads (24%) | catalogued as rs546778867, COSV63547603; called by muse, mutect2, varscan2
- PAN2 | c.1071G>T p.W357C | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV57753521; called by muse, mutect2, varscan2
- PCK1 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.213); catalogued as COSV60127379; called by muse, mutect2, varscan2
- PCM1 | c.5841T>G p.Y1947* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV59586239; called by muse, mutect2, varscan2
- PNMA5 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV62625509, COSV62626284; called by muse, mutect2, varscan2
- PRAME | c.1340G>A p.S447N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.26); catalogued as COSV67161391; called by muse, mutect2, varscan2
- PRSS22 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV99361907; called by muse, mutect2
- PRSS36 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs147050263; called by muse, mutect2, varscan2
- RCCD1 | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV62695021; called by muse, mutect2, varscan2
- REV1 | c.3382C>G p.L1128V | Missense Mutation (SNP) | VAF 49/151 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV51484060, COSV51486006; called by muse, mutect2, varscan2
- RNF123 | c.3520G>A p.V1174M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV57538264; called by muse, mutect2, varscan2
- RNF19A | c.1515G>C p.E505D | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV61992903; called by muse, mutect2, varscan2
- SIDT1 | c.2417T>G p.F806C | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53500255; called by muse, mutect2, varscan2
- SLC35G2 | c.911T>G p.F304C | Missense Mutation (SNP) | VAF 34/540 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs1430913016, COSV101262050; called by muse, mutect2
- SPHKAP | c.1299T>A p.Y433* | Nonsense Mutation (SNP) | VAF 11/59 reads (19%) | catalogued as COSV60875554; called by muse, mutect2, varscan2
- SPTB | c.5859A>T p.E1953D | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101072245; called by muse, mutect2
- TACR2 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64822099; called by muse, mutect2, varscan2
- TDRD5 | c.2140G>T p.E714* | Nonsense Mutation (SNP) | VAF 20/356 reads (6%) | catalogued as COSV99676552, COSV99677105; called by muse, mutect2
- THNSL2 | c.251T>C p.F84S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59082684; called by muse, mutect2, varscan2
- TMEM94 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as rs191852169; called by muse, mutect2, varscan2
- TUBA1C | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.403); catalogued as COSV56509979; called by muse, mutect2, varscan2
- UPF3B | c.1135C>T p.R379C (on ENST00000276201 / NM_080632.3; = p.R366C on NM_023010.3) | Missense Mutation (SNP) | VAF 115/354 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as rs761031567, COSV52229819; called by muse, mutect2, varscan2
- USP35 | c.2281G>A p.V761I | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs371671590; called by muse, mutect2, varscan2
- USP53 | c.1505A>G p.H502R | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV56793800; called by muse, mutect2, varscan2
- USP9X | c.3158C>T p.T1053M | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); catalogued as rs371450770, COSV61067969; called by muse, mutect2, varscan2
- VARS1 | c.874G>T p.V292F | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as COSV100989946; called by muse, mutect2
- VPS8 | c.542A>T p.D181V (on ENST00000625842 / NM_001349294.1; = p.D179V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV54983662; called by muse, mutect2, varscan2
- VRK3 | c.547+1G>T p.X183_splice | Splice Site (SNP) | VAF 38/110 reads (35%) | catalogued as COSV57465436; called by muse, mutect2, varscan2
- WFDC8 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 91/363 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV51489247; called by muse, mutect2, varscan2
- WIPI1 | c.937G>A p.G313R | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771913875, COSV50929859, COSV50930024; called by muse, mutect2, varscan2
- WSCD2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs894233293, COSV54581352; called by muse, varscan2
- WSCD2 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 72/194 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV54581364; called by muse, varscan2
- ZFR | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 33/131 reads (25%) | catalogued as COSV54052241; called by muse, mutect2, varscan2
- ZNF208 | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 157/409 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.239); catalogued as COSV68103844; called by muse, mutect2, varscan2
- ZNF229 | c.1759C>T p.L587F | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV52161241; called by muse, mutect2, varscan2
- ZNF585B | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.052); catalogued as rs557814772, COSV57215166; called by muse, mutect2, varscan2
- ZNF76 | c.550-1G>A p.X184_splice | Splice Site (SNP) | VAF 53/130 reads (41%) | catalogued as COSV57591306; called by muse, mutect2, varscan2
- ZNF804B | c.1137G>T p.R379S | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.212); catalogued as COSV60817290, COSV60823975; called by muse, mutect2, varscan2
- ATP7A | c.2296_2298dup p.L766dup | In Frame Ins (INS) | VAF 72/244 reads (30%) | called by mutect2, pindel, varscan2
- EYS | c.78del p.Q27Nfs*15 | Frame Shift Del (DEL) | VAF 34/130 reads (26%) | called by mutect2, pindel, varscan2
- C11orf24 | c.1266G>C p.L422= | Silent (SNP) | VAF 81/109 reads (74%) | catalogued as COSV58505382; called by muse, mutect2, varscan2
- CHST12 | c.759C>T p.S253= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV51674685; called by muse, mutect2, varscan2
- CNTN5 | c.3024T>A p.G1008= | Silent (SNP) | VAF 189/394 reads (48%) | catalogued as COSV54302482; called by muse, mutect2, varscan2
- COL4A4 | c.4707C>T p.C1569= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as rs781256511, COSV61631294; called by muse, mutect2, varscan2
- DAAM2 | c.2859G>A p.Q953= (on ENST00000274867 / NM_001201427.2; = p.Q952= on NM_015345.3) | Silent (SNP) | VAF 138/248 reads (56%) | catalogued as COSV99226152; called by muse, mutect2
- ETFB | c.132C>T p.I44= | Silent (SNP) | VAF 35/59 reads (59%) | catalogued as rs374935848, COSV58535130; called by muse, mutect2, varscan2
- FGF6 | c.306C>G p.P102= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs765855786, COSV57403745, COSV57404438; called by muse, mutect2, varscan2
- KIAA0408 | c.1962T>C p.A654= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV64115855; called by muse, mutect2, varscan2
- KIR2DS4 | c.636G>A p.P212= | Silent (SNP) | VAF 193/324 reads (60%) | catalogued as rs543819286; called by muse, mutect2, varscan2
- LRAT | c.414C>T p.N138= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs372344739; called by muse, mutect2, varscan2
- MYO16 | c.2721C>T p.Y907= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs751174402, COSV51788268; called by muse, mutect2, varscan2
- NUP153 | c.3324A>G p.Q1108= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV50448360; called by muse, mutect2, varscan2
- PCDHB5 | c.1827G>A p.T609= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as COSV50649768; called by muse, mutect2, varscan2
- PGLYRP2 | c.150T>A p.A50= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV99484104; called by muse, mutect2
- PROKR2 | c.342C>T p.Y114= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs1454126445, COSV54085714; called by muse, mutect2, varscan2
- SLITRK5 | c.1128C>T p.T376= | Silent (SNP) | VAF 37/131 reads (28%) | catalogued as rs762138298, COSV61522211; called by muse, mutect2, varscan2
- SSB | c.522G>A p.K174= | Silent (SNP) | VAF 36/105 reads (34%) | catalogued as COSV53626317; called by muse, mutect2, varscan2
- SSH1 | c.2994G>T p.P998= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV58455830; called by muse, mutect2, varscan2
- TMEFF1 | c.954C>G p.L318= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as rs746888244, COSV58492507; called by muse, mutect2, varscan2
- UBXN10 | c.114G>A p.R38= | Silent (SNP) | VAF 14/151 reads (9%) | catalogued as COSV100907818; called by muse, mutect2
- URAD | c.114C>T p.F38= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1451675497, COSV100229607; called by muse, mutect2, varscan2
- WDR36 | c.540T>C p.T180= | Silent (SNP) | VAF 13/193 reads (7%) | catalogued as COSV101540811; called by muse, mutect2
- XKR6 | c.1771A>C p.R591= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV58655524; called by muse, mutect2, varscan2
- ZNF532 | c.573G>T p.T191= | Silent (SNP) | VAF 215/575 reads (37%) | catalogued as rs371823083, COSV60172659; called by muse, mutect2, varscan2
- ARHGAP42 | c.*3889T>C | 3'UTR (SNP) | VAF 10/279 reads (4%) | catalogued as COSV100082828; called by muse, mutect2
- CHRM2 | c.-47+33837T>A | Intron (SNP) | VAF 49/151 reads (32%) | catalogued as COSV57769896; called by muse, mutect2, varscan2
- EIF4A1 | c.996+56C>G | Intron (SNP) | VAF 31/76 reads (41%) | catalogued as COSV51510487, COSV99549138; called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039799 A>T | 5'Flank (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- XIST | n.8938A>C | RNA (SNP) | VAF 22/82 reads (27%) | catalogued as rs763898096; called by muse, mutect2, varscan2
